CPTAC case C3L-04849 — Floor of mouth — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5023cef4-3bba-44ef-ae7e-8ac30bd19412

Demographics
Sex at birth: male; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Floor of mouth, NOS; Age at diagnosis: 63.2 years (23,099 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Residual disease: R1; Last known disease status: Tumor free; Days to last known disease status: 356 days; Progression or recurrence: no; Days to last follow up: 356 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.7 cm; Lymph node involvement: Positive; Lymph nodes positive: 8; Lymph nodes tested: 45; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 356 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 356 days; Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 356 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 95.2 kg; Height: 173.5 cm; BMI: 31.63.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 31.5; Cigarettes per day: 14; Tobacco smoking onset year: 1973; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 49.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04849-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 41 days; Initial weight: 156 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04849-22: Section location: Floor of Mouth; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-04849-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 41 days; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-04849-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 41 days; Method of sample procurement: Blood Draw.
